Somatic mutation profile of cancer-model specimen HCM-CSHL-0810-C54-85B (3D Organoid, passage 15; aliquot HCM-CSHL-0810-C54-85B-01D-A85L-36), derived from the primary tumor of HCMI case HCM-CSHL-0810-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC.
Specimen HCM-CSHL-0810-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8819f47f-4c3e-427f-890d-ec9661cccbc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0810-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0810-C54-11A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9697bc-793a-4fbf-a99d-2054d30e64bd

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 150/312 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57119370; called by muse, mutect2, varscan2
- ASXL3 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 200/327 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1262819510; called by muse, mutect2, varscan2
- CDH12 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 128/510 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV66385675; called by muse, mutect2, varscan2
- DNAH2 | c.8416C>T p.R2806C | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1195835191, COSV101209608; called by muse, mutect2
- EML5 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 141/600 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61345855; called by muse, mutect2, varscan2
- HELB | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56072571; called by muse, mutect2, varscan2
- LOXHD1 | c.3350+1G>A p.X1117_splice | Splice Site (SNP) | VAF 227/690 reads (33%) | catalogued as rs1301706601; called by muse, mutect2, varscan2
- MAST4 | c.5952G>C p.E1984D (on ENST00000403625 / NM_001164664.2; = p.E1795D on NM_015183.3) | Missense Mutation (SNP) | VAF 18/649 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV99846348; called by muse, mutect2
- MELK | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs764124417; called by muse, mutect2, varscan2
- OR13F1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 157/559 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191015152, COSV58251628; called by muse, mutect2, varscan2
- OR9G4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 20/760 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs147669235; called by muse, mutect2
- PCDH11X | c.3965C>A p.P1322H | Missense Mutation (SNP) | VAF 44/836 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs1182139319, COSV53441703; called by muse, mutect2
- RAB43 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 213/230 reads (93%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs772577986, COSV59348711; called by muse, mutect2, varscan2
- RFX7 | c.2089G>A p.A697T (on ENST00000559447 / NM_001368074.1; = p.A794T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs762899288; called by muse, mutect2
- ZNF208 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 74/575 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV68113091; called by muse, mutect2, varscan2
- CHD8 | c.1723_1742del p.R575Afs*15 (on ENST00000646647 / NM_001170629.2; = p.R296Afs*15 on NM_020920.4) | Frame Shift Del (DEL) | VAF 60/317 reads (19%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.3223C>G p.Q1075E | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAJB14 | c.763C>G p.P255A | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DPYSL4 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 148/892 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA2 | c.1757A>T p.K586M | Missense Mutation (SNP) | VAF 173/300 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ESR2 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); called by muse, mutect2
- FBXO15 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 21/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- H1-4 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 136/521 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 266/730 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KCNJ6 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 136/665 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS3 | c.980_983del p.Q327Pfs*37 (on ENST00000558555 / NM_001346148.1; = p.Q373Pfs*37 on NM_020160.3) | Frame Shift Del (DEL) | VAF 122/927 reads (13%) | called by mutect2, pindel, varscan2
- MEX3D | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 331/609 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYRFL | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 147/354 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAGK | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 140/412 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by mutect2, varscan2
- NEIL2 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.266); called by muse, mutect2
- NYX | c.1157G>T p.C386F | Missense Mutation (SNP) | VAF 32/1042 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- PANX2 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD6B | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 99/399 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SCN4A | c.4028A>T p.Q1343L | Missense Mutation (SNP) | VAF 15/453 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2
- SCRT1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 94/502 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTA1 | c.5068A>C p.N1690H | Missense Mutation (SNP) | VAF 183/525 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TEAD3 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UGGT2 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 71/190 reads (37%) | called by muse, mutect2, varscan2
- ZFHX3 | c.5572C>T p.L1858F | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF501 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF574 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 30/970 reads (3%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.717); called by muse, mutect2
- ADGRL1 | c.2922G>A p.P974= (on ENST00000340736 / NM_001008701.3; = p.P969= on NM_014921.5) | Silent (SNP) | VAF 153/926 reads (17%) | catalogued as rs199828718; called by muse, mutect2, varscan2
- CC2D1A | c.2310C>A p.I770= | Silent (SNP) | VAF 130/824 reads (16%) | catalogued as COSV58785564; called by muse, mutect2, varscan2
- EPS8L2 | c.1314G>A p.E438= | Silent (SNP) | VAF 14/400 reads (4%) | catalogued as rs972599529; called by muse, mutect2
- ESPNL | c.2268G>A p.P756= | Silent (SNP) | VAF 235/788 reads (30%) | catalogued as rs374701717; called by muse, mutect2, varscan2
- FCHSD1 | c.1539C>T p.H513= | Silent (SNP) | VAF 107/471 reads (23%) | catalogued as rs773839285; called by muse, mutect2, varscan2
- PEX14 | c.408G>C p.L136= | Silent (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- PTPRZ1 | c.3321C>A p.T1107= | Silent (SNP) | VAF 22/670 reads (3%) | called by muse, mutect2
- RGPD4 | c.2838C>A p.G946= | Silent (SNP) | VAF 44/666 reads (7%) | called by muse, mutect2
- SLC2A10 | c.1452G>A p.L484= | Silent (SNP) | VAF 114/545 reads (21%) | catalogued as COSV100826377; called by muse, mutect2, varscan2
- TEX11 | c.1617C>T p.T539= (on ENST00000344304; = p.T524= on NM_031276.3) | Silent (SNP) | VAF 126/435 reads (29%) | called by muse, mutect2, varscan2
- WIPI1 | c.171C>T p.I57= | Silent (SNP) | VAF 108/481 reads (22%) | called by muse, mutect2, varscan2
- TSHZ3 | c.41-28911G>A | Intron (SNP) | VAF 18/644 reads (3%) | called by muse, mutect2
